Gene-level copy-number profile of tumor specimen TCGA-DD-AAE6-01A from TCGA case TCGA-DD-AAE6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.6 years (21,764 days).
Specimen TCGA-DD-AAE6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a78cd5e8-1228-4307-807a-1f5c44ca4c82.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAE6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f8a5707-6391-48cb-9ce5-a7e0615dc12b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 7,041; copy number 3: 3,113; copy number 4: 32,303; copy number 5: 9,262; copy number 6: 2,739; copy number 7: 42; copy number 8: 3,579; copy number 9: 1,352; copy number 10: 47; copy number 11: 293; copy number 12: 3; copy number 21: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAE6-01A-11D-A40Q-01): tumor purity 0.98, ploidy 4.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,720 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–239,915,452, 24 genes, copy number 9 (within-gene range 8–9): AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2.
- chr5:58,198–1,295,068, 47 genes, copy number 10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr9:27,829,276–27,844,481, 1 gene, copy number 12: AL360014.1.
- chr11:68,261,338–69,775,341, 38 genes, copy number 9–21: C11orf24, AP002813.1, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr14:18,333,726–45,715,952, 757 genes, copy number 9 (broad region; genes not listed).
- chr14:48,045,481–51,096,061, 77 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:52,267,698–53,157,528, 22 genes, copy number 9: PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1.
- chr20:32,443,059–32,585,074, 1 gene, copy number 9 (within-gene range 4–9): NOL4L.
- chr20:32,485,149–35,002,437, 85 genes, copy number 9 (broad region; genes not listed).
- chr20:36,306,336–40,126,357, 93 genes, copy number 9 (broad region; genes not listed).
- chr20:41,024,205–41,196,801, 5 genes, copy number 9: RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871.
- chr20:41,196,647–41,197,157, 2 genes, copy number 9: AL022394.1, RPL23AP81.
- chr20:41,991,140–44,069,616, 33 genes, copy number 9: AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P.
- chr20:44,247,099–64,313,132, 535 genes, copy number 9–11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
